TCGA case TCGA-LN-A4A4 — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: ILSBIO. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e89d7900-915d-4936-b1b2-cac3670ea2f4

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 36 years; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 36.7 years (13,419 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 383 days (1.0 years); Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 68 days; Days to treatment end: 107 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, preoperative.

Follow-up (3 entries)
- Days to follow up: 3 days; Disease response: Tumor Free.
- Days to follow up: 383 days (1.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 60.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 175 cm; BMI: 20.2.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 1; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LN-A4A4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 310 mg.
  Slide TCGA-LN-A4A4-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LN-A4A4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LN-A4A4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Alcohol consumption frequency: 7; History reflux disease indicator: No; Number of relatives diagnosed: 0; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 383 days; disease-specific survival: no event (censored), 383 days; disease-free interval: no event (censored), 383 days; progression-free interval: no event (censored), 383 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LN-A4A4-01A-11D-A25X-01): tumor purity 0.64, ploidy 2.57, whole-genome doublings 1.
